Somatic mutation profile of tumor specimen 0DPHAD from CCDI case PBCDBX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 15.6 years (5,698 days).
Specimen 0DPHAD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4d452f1-919f-4b0b-a30e-7e45f7ebe4fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPH9Y (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f85ce02-4bb4-48b4-b5e4-36ccc55014be

The open-access MAF lists 3 somatic variants for this specimen: 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBLB | c.2570-62T>A | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, varscan2
- GLCCI1 | c.696+91A>G | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- MSH5 | c.1014+71C>T | Intron (SNP) | VAF 3/20 reads (15%) | called by mutect2, varscan2
